Gene-level copy-number profile of tumor specimen C3N-03755-01 from CPTAC case C3N-03755, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 68.9 years (25,165 days).
Specimen C3N-03755-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 43bb9578-f7da-438f-9c3f-8b70bf56824f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03755-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/be22e541-0168-4c91-af22-fa26ec0ae748

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 36; copy number 1: 13,685; copy number 2: 42,236; copy number 3: 2,911; copy number 4: 28; copy number 12: 2; copy number 20: 2; copy number 34: 9; copy number 35: 2.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,128,103, 14 genes (within-gene range 0–1): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr9:38,360,427–38,620,596, 16 genes (within-gene range 0–1): AL135785.1, ALDH1B1, IGFBPL1, AL390726.5, ARMC8P1, TCEA1P3, GAS2L1P1, VN1R48P, AL390726.1, FAM220BP, AL390726.4, FAM95C, AL390726.3, AL390726.2, SNX18P3, ANKRD18A.
- chr11:127,204–186,136, 3 genes (within-gene range 0–2): LINC01001, AC069287.3, RNU6-447P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 15 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,498,785–143,500,512, 2 genes, copy number 20: AC239859.2, LINC02799.
- chr7:52,165,235–52,269,569, 2 genes, copy number 35: AC079763.1, AC006320.1.
- chr7:54,759,348–55,433,742, 9 genes, copy number 34 (within-gene range 3–34): SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2.
- chr11:112,967–126,123, 2 genes, copy number 12: AC069287.1, CICP23.

Autosomal genes at a single copy (total copy number 1): 10,885. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
